Somatic mutation profile of tumor specimen TARGET-30-PAUXUP-01A (aliquot TARGET-30-PAUXUP-01A-01D) from TARGET case TARGET-30-PAUXUP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 4.6 years (1,685 days).
Specimen TARGET-30-PAUXUP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42ee51e-2c19-4959-ad08-ade3e70438ec.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUXUP-10A (Blood Derived Normal), aliquot TARGET-30-PAUXUP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39a1877e-4587-4926-acf4-d0d1c951be7e

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TJP3 | c.2426C>T p.T809M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs372401927; called by muse, mutect2, varscan2
- NALCN | c.3648C>A p.I1216= | Silent (SNP) | VAF 104/209 reads (50%) | catalogued as COSV51953973; called by muse, mutect2, varscan2
- RUNX1 | c.*2016C>G | 3'UTR (SNP) | VAF 45/153 reads (29%) | catalogued as COSV55886642; called by muse, mutect2, varscan2
